MMRF case MMRF_2244 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e5f64ec9-71e2-40d0-8f7a-0de9adba60df

Demographics
Sex at birth: female; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.0 years (18,636 days); ISS stage: II; Days to last known disease status: 823 days (2.3 years); Days to last follow up: 823 days (2.3 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 100 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 715 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 786 days (2.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 198 mg/dL; Immunoglobulin G 2.81 g/L; Immunoglobulin A 32 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.4 mmol/L; Albumin 30 g/L; Total Protein 10.2 g/dL; Glucose 5.34 mmol/L; C-Reactive Protein 1.59 mg/dL.
- Day 93 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.76 mg/dL; Immunoglobulin G 3.81 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 5.13 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 11.7 ×10⁹/L; Absolute Neutrophil 10.6 ×10⁹/L; Platelets 289 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 11.9 mmol/L.
- Day 183 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.73 mg/dL; Immunoglobulin G 5.13 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.5 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 5.28 mmol/L.
- Day 285 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.53 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.75 g/L; Immunoglobulin M 1.17 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 5.72 mmol/L.
- Day 379 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.4 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 4.14 g/L; Immunoglobulin M 1.23 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 5.61 mmol/L.
- Day 445 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.4 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 6.09 g/L; Immunoglobulin M 1.29 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 4.73 mmol/L.
- Day 554 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 31.5 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 6.49 g/L; Immunoglobulin M 1.14 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 5.94 mmol/L.
- Day 652 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 35.1 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 6.95 g/L; Immunoglobulin M 1.2 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L.
- Day 785 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 33.3 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 6.71 g/L; Immunoglobulin M 1.13 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 312 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 5.94 mmol/L.
- Day 823 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.3 mg/dL; Immunoglobulin G 7.18 g/L; Immunoglobulin A 4.56 g/L; Immunoglobulin M 0.97 g/L; Lactate Dehydrogenase 3.87 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 7 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day -17: Weight: 112 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2244_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_2244_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
